Somatic mutation profile of tumor specimen TCGA-06-0876-01A (aliquot TCGA-06-0876-01A-01W-0424-08) from TCGA case TCGA-06-0876, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 72.2 years (26,372 days).
Specimen TCGA-06-0876-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 17f6bf94-50ad-4df6-a6c9-17f614440abf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0876-10A (Blood Derived Normal), aliquot TCGA-06-0876-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9bcd45ef-9e0f-45ac-af5f-2fdfd4227503

The open-access MAF lists 90 somatic variants for this specimen: 74 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Frame Shift Ins 26, Silent 15, Nonsense Mutation 5, Frame Shift Del 2, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DCX | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 375/864 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs587783562, CM980528, COSV57565678; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EGFR | c.323G>A p.R108K | Missense Mutation (SNP) | VAF 689/2348 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519828, COSV51766433; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EGFR | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 2826/7200 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139236063, COSV51769031, COSV51808387; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- STAT5B | c.1102dup p.Q368Pfs*9 | Frame Shift Ins (INS) | VAF 100/788 reads (13%) | catalogued as rs761761205; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 528/1074 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AHR | c.422C>A p.T141N | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as COSV54121466; called by muse, mutect2
- ANKDD1A | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.207); catalogued as rs377565868; called by muse, mutect2
- ARMCX2 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 179/496 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.055); catalogued as COSV57529143; called by muse, mutect2, varscan2
- ATP2B4 | c.261dup p.K88Qfs*40 | Frame Shift Ins (INS) | VAF 16/169 reads (9%) | catalogued as rs769726180; called by mutect2, varscan2
- BNC1 | c.225dup p.M76Hfs*17 | Frame Shift Ins (INS) | VAF 13/90 reads (14%) | catalogued as rs751941533; called by mutect2, varscan2
- CENPF | c.7066G>A p.A2356T | Missense Mutation (SNP) | VAF 118/345 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV65272502; called by muse, mutect2, varscan2
- CFAP77 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV58006990; called by muse, mutect2, varscan2
- CHAT | c.1441dup p.R481Pfs*30 | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | catalogued as rs773268576; called by pindel, varscan2
- CHAT | c.2164T>C p.C722R | Missense Mutation (SNP) | VAF 149/219 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60319750; called by muse, mutect2, varscan2
- CNGA2 | c.1512T>A p.D504E | Missense Mutation (SNP) | VAF 275/727 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.068); catalogued as COSV61703018, COSV61706067; called by muse, mutect2, varscan2
- COL27A1 | c.3157C>T p.R1053* | Nonsense Mutation (SNP) | VAF 11/21 reads (52%) | catalogued as COSV61921243; called by muse, mutect2, varscan2
- CTSW | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.403); catalogued as COSV57171639; called by muse, mutect2, varscan2
- CYB5R4 | c.66dup p.R23Afs*2 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | catalogued as rs750790143; called by pindel, varscan2
- DOCK4 | c.4310G>A p.W1437* | Nonsense Mutation (SNP) | VAF 280/998 reads (28%) | catalogued as COSV70236928; called by muse, mutect2, varscan2
- DOCK8 | c.3095C>G p.A1032G | Missense Mutation (SNP) | VAF 46/212 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV66617448; called by muse, mutect2, varscan2
- DOCK8 | c.3175C>G p.L1059V | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as COSV66617455; called by muse, mutect2, varscan2
- DPT | c.538A>T p.R180W | Missense Mutation (SNP) | VAF 128/339 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63189483; called by muse, mutect2, varscan2
- DYNAP | c.414C>A p.N138K (on ENST00000321600; = p.N112K on NM_173629.3) | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.057); catalogued as rs1331210288, COSV58665936; called by muse, mutect2, varscan2
- EIF4B | c.988dup p.Q330Pfs*14 | Frame Shift Ins (INS) | VAF 11/104 reads (11%) | catalogued as rs747252313; called by mutect2, varscan2
- EPS8L3 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV62608695; called by muse, mutect2, varscan2
- FAM151A | c.351dup p.T118Hfs*5 | Frame Shift Ins (INS) | VAF 46/344 reads (13%) | catalogued as rs749953492; called by mutect2, varscan2
- FAM83E | c.889dup p.Q297Pfs*33 | Frame Shift Ins (INS) | VAF 6/26 reads (23%) | catalogued as rs773971919; called by mutect2, varscan2
- FHDC1 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.453); catalogued as rs149221149; called by muse, mutect2, varscan2
- FNTB | c.1047dup p.L350Afs*4 | Frame Shift Ins (INS) | VAF 30/249 reads (12%) | catalogued as rs768774237; called by mutect2, varscan2
- GFOD1 | c.348C>A p.S116R | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64954448; called by muse, mutect2, varscan2
- GPC2 | c.1666dup p.A556Gfs*141 | Frame Shift Ins (INS) | VAF 8/28 reads (29%) | catalogued as rs753572388; called by mutect2, varscan2
- IFNG | c.334C>T p.R112* | Nonsense Mutation (SNP) | VAF 157/398 reads (39%) | catalogued as COSV57490528; called by muse, mutect2, varscan2
- IRS4 | c.1772dup p.K592Qfs*12 | Frame Shift Ins (INS) | VAF 38/280 reads (14%) | catalogued as rs780982673; called by mutect2, varscan2
- KLF1 | c.835C>T p.H279Y | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs777110892, COSV53434412; called by mutect2, varscan2
- LPIN3 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as rs747237851, COSV64718247; called by muse, mutect2
- LRP1 | c.12575dup p.D4193Rfs*9 | Frame Shift Ins (INS) | VAF 42/272 reads (15%) | catalogued as rs757410385; called by mutect2, varscan2
- LRRC8B | c.1834G>A p.E612K | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV58372919; called by muse, mutect2, varscan2
- MIDEAS | c.939dup p.N314Qfs*38 | Frame Shift Ins (INS) | VAF 12/68 reads (18%) | catalogued as rs762448666; called by mutect2, varscan2
- MUC3A | c.8484T>A p.Y2828* | Nonsense Mutation (SNP) | VAF 137/1015 reads (13%) | catalogued as COSV100113748; called by muse, mutect2, varscan2
- MX2 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 45/619 reads (7%) | SIFT tolerated (0.89); PolyPhen benign (0.227); catalogued as rs745448850, COSV58096513; called by muse, mutect2
- N4BP2L2 | c.2305C>T p.Q769* (on ENST00000674422; = p.Q340* on NM_033111.4) | Nonsense Mutation (SNP) | VAF 58/187 reads (31%) | catalogued as COSV62631424; called by muse, mutect2, varscan2
- NR3C2 | c.740G>A p.R247K | Missense Mutation (SNP) | VAF 239/474 reads (50%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.033); catalogued as COSV60985062; called by muse, mutect2, varscan2
- NRXN1 | c.1851dup p.L618Afs*5 | Frame Shift Ins (INS) | VAF 18/152 reads (12%) | catalogued as rs768883697; called by mutect2, varscan2
- NRXN2 | c.808dup p.A270Gfs*27 | Frame Shift Ins (INS) | VAF 30/156 reads (19%) | catalogued as rs754860965; called by mutect2, varscan2
- OR2K2 | c.295G>A p.D99N (on ENST00000374428; = p.D70N on NM_205859.2) | Missense Mutation (SNP) | VAF 80/162 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57016072; called by muse, mutect2, varscan2
- OR6C70 | c.220G>T p.A74S | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs749540632, COSV59244469, COSV59245508; called by muse, mutect2, varscan2
- PCDHA2 | c.1354G>A p.A452T | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.453); catalogued as rs782095286, COSV65366989; called by muse, mutect2, varscan2
- PI4KA | c.658C>G p.L220V | Missense Mutation (SNP) | VAF 452/1169 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV55403434; called by muse, mutect2, varscan2
- PIGV | c.397G>T p.A133S | Missense Mutation (SNP) | VAF 30/1030 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.418); catalogued as COSV50291238; called by muse, mutect2
- PLXNA2 | c.92dup p.A32Sfs*13 | Frame Shift Ins (INS) | VAF 10/74 reads (14%) | catalogued as rs756284848; called by mutect2, varscan2
- PPRC1 | c.2819dup p.P941Tfs*75 | Frame Shift Ins (INS) | VAF 41/246 reads (17%) | catalogued as rs768056539; called by mutect2, varscan2
- PRCC | c.1138dup p.Q380Pfs*12 | Frame Shift Ins (INS) | VAF 57/338 reads (17%) | catalogued as rs778683789; called by mutect2, varscan2
- PTEN | c.136T>C p.Y46H | Missense Mutation (SNP) | VAF 135/189 reads (71%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV64296748, COSV64297491; called by muse, mutect2, varscan2
- PXN | c.1465T>G p.S489A (on ENST00000228307 / NM_001080855.3; = p.S455A on NM_002859.4) | Missense Mutation (SNP) | VAF 176/451 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV57218775; called by muse, mutect2, varscan2
- RAB4B | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.397); catalogued as COSV63824801; called by muse, mutect2
- RGS14 | c.866T>C p.L289P | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.642); catalogued as rs775508379, COSV68770837; called by muse, mutect2, varscan2
- RUBCN | c.830dup p.V278Sfs*16 | Frame Shift Ins (INS) | VAF 19/94 reads (20%) | catalogued as rs745498865; called by mutect2, varscan2
- SDCBP | c.750G>A p.K250= | Splice Region (SNP) | VAF 63/199 reads (32%) | catalogued as COSV50683645; called by muse, mutect2, varscan2
- SEMG1 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs199672858, COSV54871705, COSV54872099; called by muse, mutect2, varscan2
- SERPINB12 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs770606706, COSV54032059; called by muse, mutect2, varscan2
- SH3PXD2A | c.328dup p.H110Pfs*6 | Frame Shift Ins (INS) | VAF 8/27 reads (30%) | catalogued as rs777796332; called by mutect2, varscan2
- SHC1 | c.1087dup p.V363Gfs*61 (on ENST00000368445 / NM_183001.5; = p.V253Gfs*62 on NM_003029.5) | Frame Shift Ins (INS) | VAF 52/344 reads (15%) | catalogued as rs746556543; called by mutect2, varscan2
- SHC1 | c.92dup p.E32Gfs*23 | Frame Shift Ins (INS) | VAF 17/126 reads (13%) | catalogued as rs752843778; called by mutect2, varscan2
- SMOX | c.908dup p.R304Qfs*4 | Frame Shift Ins (INS) | VAF 21/180 reads (12%) | catalogued as rs746816975; called by mutect2, varscan2
- TFE3 | c.1445dup p.P483Tfs*138 | Frame Shift Ins (INS) | VAF 36/184 reads (20%) | catalogued as rs782753958; called by mutect2, varscan2
- TTC13 | c.1801del p.I601Lfs*3 | Frame Shift Del (DEL) | VAF 16/40 reads (40%) | catalogued as COSV64167701; called by mutect2, pindel, varscan2
- ZKSCAN1 | c.466G>A p.G156R | Missense Mutation (SNP) | VAF 33/206 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV60874017; called by muse, mutect2, varscan2
- ZKSCAN4 | c.1508T>C p.I503T | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.346); catalogued as rs968209334, COSV66022998; called by muse, mutect2, varscan2
- ZNFX1 | c.3775A>C p.M1259L | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV65593956; called by muse, mutect2, varscan2
- AC006059.2 | c.732G>A p.M244I | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CLSPN | c.730_734del p.V244Kfs*17 | Frame Shift Del (DEL) | VAF 36/136 reads (26%) | called by mutect2, pindel, varscan2
- FRMPD1 | c.4001G>C p.C1334S | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- KIAA0513 | c.741dup p.L248Afs*66 | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | called by pindel, varscan2
- MBTPS1 | c.1218dup p.C407Vfs*29 | Frame Shift Ins (INS) | VAF 3/21 reads (14%) | called by pindel, varscan2
- ADAMDEC1 | c.579C>T p.D193= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs141288918; called by muse, mutect2, varscan2
- ADRA1B | c.114C>T p.P38= | Silent (SNP) | VAF 51/113 reads (45%) | catalogued as COSV60700464; called by muse, mutect2, varscan2
- AIPL1 | c.87C>T p.T29= | Silent (SNP) | VAF 32/55 reads (58%) | catalogued as COSV51505808; called by muse, mutect2, varscan2
- AMMECR1L | c.255G>T p.A85= | Silent (SNP) | VAF 73/208 reads (35%) | catalogued as rs563618984, COSV55759851; called by muse, mutect2, varscan2
- ARSF | c.1260G>A p.Q420= | Silent (SNP) | VAF 58/159 reads (36%) | catalogued as COSV63838891; called by muse, varscan2
- CD33 | c.321C>T p.D107= | Silent (SNP) | VAF 53/128 reads (41%) | catalogued as rs141721735; called by muse, mutect2, varscan2
- HHAT | c.963C>T p.L321= | Silent (SNP) | VAF 63/137 reads (46%) | catalogued as COSV54790973; called by muse, mutect2, varscan2
- HUWE1 | c.10881C>T p.A3627= | Silent (SNP) | VAF 141/337 reads (42%) | catalogued as rs1351146606, COSV53333861; called by muse, mutect2, varscan2
- KCNJ12 | c.1056C>T p.P352= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV59166830, COSV59167269; called by mutect2, varscan2
- KRTAP10-8 | c.402C>T p.C134= | Silent (SNP) | VAF 41/373 reads (11%) | catalogued as rs782140997, COSV58166322; called by muse, mutect2, varscan2
- NRK | c.1476G>A p.Q492= | Silent (SNP) | VAF 33/88 reads (38%) | catalogued as COSV54596589; called by muse, mutect2, varscan2
- OR4X2 | c.201C>T p.S67= | Silent (SNP) | VAF 90/248 reads (36%) | catalogued as rs773448537, COSV56582035, COSV56585087; called by muse, mutect2, varscan2
- SIGLEC9 | c.741C>T p.D247= | Silent (SNP) | VAF 33/72 reads (46%) | catalogued as rs774357117, COSV51582435, COSV51585838; called by muse, mutect2, varscan2
- SOWAHD | c.858G>A p.S286= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as rs1219284491, COSV59649412; called by muse, mutect2
- ZNF208 | c.2226T>C p.I742= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV68105502; called by muse, varscan2
- TRIM10 | c.*217G>A | 3'UTR (SNP) | VAF 18/48 reads (38%) | catalogued as COSV64998070; called by muse, mutect2, varscan2
